Somatic mutation profile of tumor specimen TCGA-F1-6874-01A (aliquot TCGA-F1-6874-01A-11D-1882-08) from TCGA case TCGA-F1-6874, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 79.6 years (29,083 days).
Specimen TCGA-F1-6874-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f59aca99-c4ee-4e9e-bdb1-0d696728671b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F1-6874-10A (Blood Derived Normal), aliquot TCGA-F1-6874-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d3dd8d-6f24-490f-a6e8-bd4d3723d911

The open-access MAF lists 1,070 somatic variants for this specimen: 809 protein-altering or splice-affecting, 233 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 494, Silent 233, Frame Shift Del 197, Frame Shift Ins 50, Nonsense Mutation 35, Splice Site 13, In Frame Del 10, Intron 10, Splice Region 7, 3'Flank 5, 5'Flank 4, RNA 4.

Variants (750 of 1,070; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 37/149 reads (25%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BMPR2 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as rs1060502581, CD1513986, CM043449, COSV65807609; ClinVar: pathogenic; called by muse, mutect2
- CDH1 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 116/391 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555515925, COSV55728800, COSV55733458; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A1 | c.1127del p.P376Lfs*165 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | catalogued as rs72645369, CD961894; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 37/138 reads (27%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- SBDS | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as rs113993998, CM043082, COSV55887178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 58/94 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104369596, COSV52785566, COSV53679279; called by muse, mutect2, varscan2
- AADACL3 | c.754_755insG p.F252Cfs*25 | Frame Shift Ins (INS) | VAF 43/204 reads (21%) | catalogued as rs1553152380; called by mutect2, pindel, varscan2
- AASDH | c.2581A>G p.T861A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1450205090, COSV52704486; called by muse, mutect2, varscan2
- ABCA7 | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV54025165; called by muse, mutect2, varscan2
- ABCB4 | c.2369T>C p.M790T | Missense Mutation (SNP) | VAF 57/302 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV55932886; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ACE2 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53023984; called by muse, mutect2, varscan2
- ACSS1 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as COSV60218236; called by muse, mutect2, varscan2
- ACTR1A | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs375160426; called by muse, mutect2, varscan2
- ACVR1 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55116996; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 50/99 reads (51%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAL | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67500143; called by muse, mutect2, varscan2
- ADAM22 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as rs1321767325, COSV55971481; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADARB2 | c.1513C>T p.L505= | Splice Region (SNP) | VAF 41/189 reads (22%) | catalogued as rs1391955136, COSV67216629; called by muse, mutect2, varscan2
- ADGRA2 | c.1573dup p.A525Gfs*59 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | catalogued as rs760256806; called by mutect2, varscan2
- ADGRG3 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.155); catalogued as rs771429590, COSV59650387; called by muse, mutect2, varscan2
- ADGRG5 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758492374, COSV61082714; called by muse, mutect2, varscan2
- ADIPOQ | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as rs200936740, COSV57858568; called by muse, mutect2, varscan2
- ADNP | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV62424659; called by muse, mutect2, varscan2
- ADRA1B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs758643818, COSV60700741; called by muse, mutect2, varscan2
- AFAP1L1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs755876664, COSV57044011; called by muse, mutect2, varscan2
- AFF3 | c.505A>G p.R169G | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV57843496; called by muse, mutect2, varscan2
- AGRN | c.5833G>A p.V1945M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as rs145079121; called by muse, mutect2, varscan2
- AHDC1 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV55937155; called by muse, mutect2, varscan2
- AHNAK2 | c.3362A>G p.D1121G | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV60909466; called by muse, mutect2, varscan2
- AKAP9 | c.10202G>A p.R3401Q (on ENST00000359028; = p.R3377Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62340589; called by muse, mutect2, varscan2
- ALDH1L1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV56411496; called by muse, mutect2, varscan2
- ALPI | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372014965; called by muse, mutect2
- AMBRA1 | c.3109C>T p.R1037* (on ENST00000458649 / NM_001367468.1; = p.R947* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 63/194 reads (32%) | catalogued as COSV54049819; called by muse, mutect2, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- AMPD2 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1291080959, COSV56646554; called by muse, mutect2, varscan2
- AMPH | c.1182G>A p.P394= | Splice Region (SNP) | VAF 16/95 reads (17%) | catalogued as rs936634704, COSV57735240; called by muse, mutect2, varscan2
- ANKIB1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs187952686; called by muse, mutect2, varscan2
- ANKRD52 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1194868258, COSV57282957; called by muse, mutect2, varscan2
- AOX1 | c.2430G>T p.K810N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021788, COSV65984502; called by muse, mutect2, varscan2
- AP5B1 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100375922; called by muse, mutect2
- APBB1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs139345068; called by muse, mutect2, varscan2
- APOB | c.3070A>G p.R1024G | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1184276566, COSV51926324; called by muse, mutect2, varscan2
- ARFGEF1 | c.4134G>T p.W1378C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51603832; called by muse, mutect2, varscan2
- ARFGEF2 | c.1784G>T p.R595M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV64210998; called by muse, mutect2, varscan2
- ARGLU1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as rs1402870612, COSV62271387; called by muse, mutect2, varscan2
- ARHGAP30 | c.3002T>C p.V1001A (on ENST00000368013 / NM_001025598.2; = p.V790A on NM_181720.3) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV63515155; called by muse, mutect2, varscan2
- ARHGAP32 | c.4630G>A p.A1544T (on ENST00000310343 / NM_001378025.1; = p.A1195T on NM_014715.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs756000808, COSV59844185; called by muse, mutect2, varscan2
- ARHGAP32 | c.1373T>A p.L458H (on ENST00000310343 / NM_001378025.1; = p.L109H on NM_014715.4) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59844199; called by muse, mutect2, varscan2
- ARHGEF10 | c.1831_1832del p.D611Cfs*2 (on ENST00000398564; = p.D586Cfs*2 on NM_014629.4) | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs749021787; called by pindel, varscan2
- ARHGEF28 | c.4252C>T p.R1418* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs756393972, COSV55249018; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 32/123 reads (26%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARMC3 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs199547387, COSV53058095; called by muse, mutect2, varscan2
- ARMC6 | c.391G>A p.A131T (on ENST00000392336; = p.A106T on NM_033415.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145390530; called by muse, mutect2, varscan2
- ARRDC4 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs140102944; called by muse, mutect2, varscan2
- ART1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs561441207, COSV51703183; called by muse, mutect2, varscan2
- ASXL1 | c.4315G>A p.A1439T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60104326; called by muse, mutect2
- ATG9B | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs570781096, COSV52486715; called by muse, mutect2, varscan2
- ATN1 | c.764del p.P255Hfs*43 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1555143544, COSV63112070; called by mutect2, pindel, varscan2
- ATP12A | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54513350; called by muse, mutect2, varscan2
- ATP1A1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401759980, COSV55190063; called by muse, mutect2, varscan2
- ATP2B4 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1352897227, COSV58174912; called by muse, mutect2, varscan2
- ATP5IF1 | c.247_249del p.K83del | In Frame Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs746429737; called by pindel, varscan2
- ATP6AP1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV63895354; called by muse, mutect2, varscan2
- ATP8B1 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52173482; called by muse, mutect2
- ATP9A | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 47/200 reads (24%) | catalogued as COSV58764084; called by muse, mutect2, varscan2
- AURKB | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60243804; called by muse, mutect2, varscan2
- B3GAT1 | c.130del p.R44Dfs*46 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV100437892; called by mutect2, varscan2
- B3GAT1 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV56995510; called by muse, mutect2, varscan2
- BBX | c.1355del p.K452Rfs*49 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as rs1560134117; called by mutect2, pindel, varscan2
- BCHE | c.1745T>C p.M582T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52254286; called by muse, mutect2, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as CM025285, COSV52257903; called by mutect2, pindel, varscan2
- BCL11A | c.1724C>T p.P575L (on ENST00000335712 / NM_001365609.1; = p.P609L on NM_018014.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1466757077, COSV59625455; called by muse, mutect2, varscan2
- BCL2L14 | c.821T>C p.L274P | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53784258; called by muse, mutect2, varscan2
- BCL9L | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV52682629; called by muse, mutect2, varscan2
- BCORL1 | c.4973G>T p.R1658M | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54390992, COSV54398079; called by muse, mutect2, varscan2
- BICDL1 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs777352984, COSV57492665; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | catalogued as rs1413008697, COSV60208966; called by mutect2, pindel
- C1QTNF2 | c.334G>A p.G112S (on ENST00000393975; = p.G67S on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs746934576, COSV67432456; called by muse, mutect2, varscan2
- C1orf115 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs763165764, COSV54273419; called by muse, mutect2, varscan2
- C3 | c.2670del p.K891Sfs*13 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | catalogued as rs750770711, COSV99837243; called by mutect2, pindel, varscan2
- C7orf33 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV61022840; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs750339990; called by mutect2, pindel
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2, varscan2
- CACNA1H | c.6235G>A p.V2079I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367607849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV54945554; called by muse, mutect2, varscan2
- CADPS | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1188760041, COSV51870431; called by muse, mutect2, varscan2
- CADPS2 | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57352466; called by muse, mutect2, varscan2
- CAND2 | c.3664_3666del p.K1222del (on ENST00000456430 / NM_001162499.2; = p.K1105del on NM_012298.3) | In Frame Del (DEL) | VAF 16/148 reads (11%) | catalogued as rs774033982; called by mutect2, pindel, varscan2
- CAPN15 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350975135, COSV54834557; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CASZ1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs751917839, COSV100682330, COSV59732820; called by muse, mutect2, varscan2
- CATIP | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs764364540, COSV56822268; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs781790231; called by mutect2, varscan2
- CCS | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747428310, COSV59578241; called by muse, mutect2, varscan2
- CD101 | c.1595T>A p.V532D | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV56716097, COSV56716569; called by muse, mutect2
- CD226 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.146); catalogued as COSV54610546; called by muse, mutect2, varscan2
- CD68 | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs201915768, COSV51510046; called by muse, mutect2, varscan2
- CDC23 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs745709624, COSV67509303; called by muse, mutect2, varscan2
- CDC34 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); catalogued as rs768815065, COSV53116161; called by muse, mutect2, varscan2
- CDH18 | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV56906681; called by muse, mutect2, varscan2
- CDH3 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs527796702, COSV50555371; called by muse, mutect2, varscan2
- CDH4 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748813585, COSV64644258; called by muse, mutect2, varscan2
- CELSR2 | c.6184G>A p.A2062T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766391495, COSV54768044; called by mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CES2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57696189; called by muse, mutect2, varscan2
- CHD4 | c.5321G>T p.R1774M (on ENST00000357008 / NM_001363606.2; = p.R1785M on NM_001273.5) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58896110; called by muse, mutect2, varscan2
- CHD4 | c.1435del p.R479Vfs*7 (on ENST00000357008 / NM_001363606.2; = p.R492Vfs*7 on NM_001273.5) | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | catalogued as COSV100538060; called by mutect2, pindel, varscan2
- CHD9 | c.8175G>T p.L2725F (on ENST00000398510 / NM_001382353.1; = p.L2709F on NM_025134.7) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV54608367; called by muse, mutect2, varscan2
- CHERP | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV52222854; called by muse, mutect2, varscan2
- CHORDC1 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV57705574; called by muse, mutect2, varscan2
- CHST1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs747016488, COSV57322138; called by muse, mutect2, varscan2
- CHST5 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100291825, COSV60337465; called by muse, varscan2
- CIC | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50547229; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs752250702; called by mutect2, varscan2
- CKM | c.1096_1098del p.K366del | In Frame Del (DEL) | VAF 86/325 reads (26%) | catalogued as rs780083622; called by pindel, varscan2
- CLCN4 | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs751105638, COSV66465413; called by muse, mutect2, varscan2
- CLDN9 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV60910237; called by muse, mutect2, varscan2
- CLIP2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1463617123, COSV56275506; called by muse, mutect2, varscan2
- CLN5 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV66283588; called by muse, mutect2, varscan2
- CLPTM1 | c.844A>G p.N282D | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61611322; called by muse, mutect2, varscan2
- CMAS | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV57556143; called by muse, mutect2, varscan2
- CNTN4 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61869130; called by muse, mutect2, varscan2
- COBLL1 | c.3046G>A p.G1016S (on ENST00000392717; = p.G978S on NM_014900.5) | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756784317, COSV52063938; called by muse, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs374805044; called by mutect2, varscan2
- COL15A1 | c.3710G>A p.C1237Y | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66641908; called by muse, mutect2
- COL24A1 | c.1661A>G p.Q554R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV65302968; called by muse, mutect2, varscan2
- COL6A6 | c.3719C>A p.A1240D | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62019419; called by muse, mutect2, varscan2
- COLEC12 | c.1586del p.P529Rfs*117 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs751632960; called by mutect2, pindel, varscan2
- CPS1 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51803919; called by muse, mutect2, varscan2
- CRB2 | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as COSV63502093; called by muse, mutect2, varscan2
- CREB5 | c.1369G>T p.E457* (on ENST00000357727 / NM_182898.4; = p.E450* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 50/261 reads (19%) | catalogued as COSV63218053, COSV63220307; called by muse, mutect2, varscan2
- CREBBP | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs747877878, COSV52116054; called by muse, mutect2, varscan2
- CRISPLD1 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 55/196 reads (28%) | catalogued as COSV51545074; called by muse, mutect2, varscan2
- CRYBA2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55387789; called by muse, varscan2
- CSF1R | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs149911279, COSV53830159, COSV53833326; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSTF1 | c.813T>A p.N271K | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV53858115; called by muse, mutect2, varscan2
- CTCF | c.2070del p.E691Sfs*30 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs1400980130; called by mutect2, varscan2
- CTDSPL2 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV52945031; called by muse, mutect2, varscan2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 42/146 reads (29%) | catalogued as rs759618368; called by mutect2, varscan2
- CUBN | c.6277G>A p.G2093S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759351780, COSV100913631, COSV64709447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL1 | c.484-2A>G p.X162_splice | Splice Site (SNP) | VAF 31/126 reads (25%) | catalogued as COSV57387146; called by muse, mutect2, varscan2
- CUL3 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.136); catalogued as rs775935313, COSV52362095; called by muse, mutect2, varscan2
- CUL9 | c.6346C>T p.P2116S | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52726131; called by muse, mutect2, varscan2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 42/250 reads (17%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYP2B6 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs770007043, COSV57842763; called by muse, varscan2
- CYP2D6 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs79489631; called by muse, mutect2, varscan2
- CYP3A7 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as rs757427192, COSV60480761; called by muse, mutect2, varscan2
- CYP4F22 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs990606848, COSV54107027; called by muse, mutect2, varscan2
- DBI | c.257G>T p.G86V (on ENST00000355857 / NM_001079862.3; = p.G103V on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100275784; called by muse, mutect2, varscan2
- DCAF11 | c.872T>G p.V291G | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV58108459; called by muse, mutect2, varscan2
- DCLRE1C | c.1156G>T p.E386* (on ENST00000378278 / NM_001350965.2; = p.E271* on NM_022487.4) | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as COSV63182184; called by muse, mutect2, varscan2
- DCSTAMP | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV52576570; called by muse, mutect2, varscan2
- DDHD1 | c.565A>G p.T189A (on ENST00000323669; = p.T386A on NM_030637.3) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV60357687; called by muse, mutect2, varscan2
- DDIAS | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1173165837, COSV61271647; called by muse, mutect2, varscan2
- DDX17 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.856); catalogued as rs774718067, COSV53246768; called by muse, mutect2, varscan2
- DENND2A | c.1514A>C p.Q505P | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV52047934; called by muse, mutect2, varscan2
- DENND3 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755436456, COSV52801203; called by muse, mutect2, varscan2
- DESI1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs770564442, COSV54354086; called by muse, mutect2, varscan2
- DGCR2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs776627102, COSV54216846, COSV99075874; called by muse, mutect2, varscan2
- DHRS7B | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100683874; called by muse, mutect2, varscan2
- DIS3 | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as COSV66705782, COSV66706729; called by muse, mutect2, varscan2
- DLC1 | c.2292C>A p.S764R (on ENST00000276297 / NM_001348081.2; = p.S327R on NM_006094.5) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV52292992; called by muse, varscan2
- DNAH10 | c.3386C>T p.S1129L (on ENST00000409039; = p.S1068L on NM_207437.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs200822383, COSV68989268; called by muse, mutect2, varscan2
- DNAH3 | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV54507736; called by muse, mutect2, varscan2
- DNAH5 | c.13106del p.P4369Qfs*8 | Frame Shift Del (DEL) | VAF 27/144 reads (19%) | catalogued as rs1561096372; called by mutect2, pindel, varscan2
- DNAJB2 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1442415535, COSV55346117; called by muse, mutect2, varscan2
- DNAJC1 | c.629del p.N210Mfs*5 | Frame Shift Del (DEL) | VAF 46/187 reads (25%) | catalogued as rs767116339; called by mutect2, pindel, varscan2
- DNAJC13 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs373430445; called by muse, mutect2, varscan2
- DNAJC16 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs746250260, COSV65435663; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK3 | c.5941C>T p.R1981C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1553618635, COSV56507659; called by muse, mutect2, varscan2
- DOCK7 | c.3045+1G>C p.X1015_splice (on ENST00000635253 / NM_001367561.1; = p.X984_splice on NM_033407.3) | Splice Site (SNP) | VAF 22/102 reads (22%) | catalogued as COSV51997877, COSV51997951; called by muse, mutect2, varscan2
- DRD2 | c.1196G>C p.C399S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60755082; called by muse, mutect2, varscan2
- DST | c.17682G>T p.Q5894H (on ENST00000361203 / NM_001374722.1; = p.Q3591H on NM_015548.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV55001280, COSV99759077; called by muse, mutect2, varscan2
- DUSP11 | c.217_219del p.K73del | In Frame Del (DEL) | VAF 22/114 reads (19%) | catalogued as rs769291574; called by pindel, varscan2
- DUSP14 | c.559_561del p.K187del | In Frame Del (DEL) | VAF 28/123 reads (23%) | catalogued as rs770878022; called by mutect2, pindel, varscan2
- DYNC1I1 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61456921; called by muse, mutect2, varscan2
- DZANK1 | c.2258A>G p.*753Wext*2 (on ENST00000262547 / NM_001099407.1; = p.*560Wext*2 on NM_018152.3 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52748368; called by muse, mutect2
- EDAR | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450239, COSV51500429; called by muse, mutect2, varscan2
- EGR1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53518299; called by muse, mutect2
- ELF3 | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62837471; called by muse, mutect2, varscan2
- ELP3 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754899290, COSV56458007; called by muse, mutect2, varscan2
- ENPP7 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as rs369080546; called by muse, mutect2, varscan2
- EPB41L1 | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV52434735, COSV99149485; called by muse, mutect2, varscan2
- EPHA1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs199931138, COSV51969266; called by muse, mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | catalogued as rs1449193125; called by mutect2, pindel, varscan2
- EPHB6 | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV63890852; called by muse, mutect2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 40/203 reads (20%) | catalogued as rs756407271; called by mutect2, pindel, varscan2
- EPPIN | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV60548045; called by muse, mutect2, varscan2
- ERBB4 | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs763644012, COSV61470138; called by muse, mutect2, varscan2
- ERICH3 | c.2399A>G p.E800G | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58601208; called by muse, mutect2, varscan2
- ETFA | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV51211212; called by muse, mutect2, varscan2
- EVX2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57962662; called by muse, mutect2, varscan2
- FA2H | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV54725457; called by muse, mutect2, varscan2
- FAM214A | c.2042dup p.N681Kfs*2 | Frame Shift Ins (INS) | VAF 23/80 reads (29%) | catalogued as rs762546731; called by mutect2, varscan2
- FAR2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 78/336 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs375583380; called by muse, mutect2, varscan2
- FARSA | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.68); catalogued as rs758807793, COSV58904476; called by muse, mutect2, varscan2
- FBN1 | c.8188C>T p.R2730W | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1371152380, COSV57311133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO41 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs775115355, COSV54582447; called by muse, mutect2, varscan2
- FBXO48 | c.83del p.N28Mfs*33 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs1558521143; called by mutect2, pindel, varscan2
- FBXO6 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV65100413, COSV65100609; called by muse, mutect2, varscan2
- FFAR4 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 42/144 reads (29%) | catalogued as COSV65159710; called by muse, mutect2, varscan2
- FGFRL1 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53256575; called by muse, mutect2, varscan2
- FH | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs778578307, COSV63817649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIP1L1 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV55782841; called by muse, varscan2
- FKBP10 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58635265; called by muse, mutect2
- FKBP8 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs544946458, COSV55891350; called by muse, mutect2, varscan2
- FKRP | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1481578790, COSV59358236; called by muse, mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 31/131 reads (24%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXN1 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV56880757; called by muse, mutect2, varscan2
- FOXN4 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200708160, COSV54492473; called by muse, mutect2, varscan2
- FRG2 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.644); catalogued as COSV66459720; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD1 | c.4468G>A p.V1490M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs538189016, COSV66699354; called by muse, mutect2, varscan2
- FSCN3 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768120886, COSV50000398; called by muse, mutect2, varscan2
- FUT8 | c.1325A>G p.Y442C (on ENST00000360689 / NM_001371534.1; = p.Y279C on NM_004480.4) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61281031; called by muse, mutect2, varscan2
- GABBR1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as rs780190021, COSV63541292; called by muse, mutect2, varscan2
- GABRE | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs769555117, COSV64819089; called by muse, mutect2, varscan2
- GAPDHS | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as rs750502242, COSV55880079; called by muse, mutect2, varscan2
- GART | c.2053G>T p.G685* | Nonsense Mutation (SNP) | VAF 25/140 reads (18%) | catalogued as COSV67818161; called by muse, mutect2, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs78929040; called by mutect2, pindel, varscan2
- GAS7 | c.1120A>G p.R374G (on ENST00000432992 / NM_201433.2; = p.R234G on NM_003644.3) | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV60432635; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs763147690; called by mutect2, varscan2
- GLCCI1 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56200386, COSV56204331, COSV99780200; called by muse, mutect2, varscan2
- GLI3 | c.4726C>A p.L1576I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67885997; called by muse, mutect2, varscan2
- GLI3 | c.2486G>A p.G829D | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV67885999; called by muse, mutect2, varscan2
- GLI3 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as rs141220299, COSV101229954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GMPPA | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1260603843, COSV58006238; called by muse, mutect2, varscan2
- GNS | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV50694078; called by muse, mutect2, varscan2
- GOLGA2 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.683); catalogued as rs142168936, COSV60791715; called by muse, mutect2, varscan2
- GOLGA6B | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755271288, COSV69769909, COSV69770717; called by muse, mutect2, varscan2
- GPIHBP1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs147455726, COSV100427344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR146 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs146511290; called by muse, mutect2, varscan2
- GPR78 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780580777, COSV66762610, COSV66764007; called by muse, mutect2, varscan2
- GPS1 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV57647873; called by muse, varscan2
- GRIA1 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53592094; called by muse, mutect2, varscan2
- GRIA2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52384411; called by muse, mutect2, varscan2
- GRIA2 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52384429; called by muse, mutect2, varscan2
- GRIK3 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66136434; called by muse, mutect2, varscan2
- GSAP | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV57528604; called by muse, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 39/126 reads (31%) | catalogued as rs754199513; called by mutect2, varscan2
- GSR | c.800T>A p.L267H | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55319642; called by muse, mutect2
- GTF2I | c.878_880del p.E293del (on ENST00000573035 / NM_032999.4; = p.E273del on NM_001518.5) | In Frame Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs782589088; called by mutect2, pindel, varscan2
- GTF3C1 | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.184); catalogued as COSV62239425; called by muse, mutect2, varscan2
- GTF3C3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV55831221; called by muse, mutect2, varscan2
- GTF3C4 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs1340310794, COSV64645022; called by muse, mutect2, varscan2
- GUCA2A | c.233T>A p.L78H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1467999631, COSV63691259; called by muse, mutect2, varscan2
- GUF1 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as COSV55781700; called by muse, mutect2, varscan2
- GUK1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368879259; called by muse, mutect2, varscan2
- GXYLT1 | c.1282del p.S428Vfs*2 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as COSV55133567; called by mutect2, pindel, varscan2
- GYG1 | c.352_353del p.E118Rfs*12 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs753901064; called by pindel, varscan2
- H1-7 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs759412124, COSV58601800; called by muse, mutect2, varscan2
- HECW1 | c.2338G>A p.V780M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs377512268; called by mutect2, varscan2
- HERC2 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV55311580; called by muse, mutect2, varscan2
- HGFAC | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs767158380, COSV66976690; called by mutect2, varscan2
- HIC2 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); catalogued as COSV68041768; called by muse, mutect2, varscan2
- HIRIP3 | c.587G>A p.S196N | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54229026; called by muse, mutect2, varscan2
- HLA-B | c.1012+1G>A p.X338_splice | Splice Site (SNP) | VAF 43/109 reads (39%) | catalogued as COSV69520626; called by muse, mutect2, varscan2
- HMCN1 | c.12828G>T p.Q4276H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV54882667; called by muse, mutect2, varscan2
- HOXA1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56065412; called by muse, mutect2, varscan2
- HTR2C | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV52203493; called by muse, mutect2, varscan2
- IFITM5 | c.148T>C p.C50R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV66887793; called by muse, mutect2, varscan2
- IGHG1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs374920757; called by muse, mutect2, varscan2
- IGSF22 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs766499669, COSV60031621; called by muse, mutect2, varscan2
- IL21R | c.1549del p.R517Gfs*38 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs748992699; called by mutect2, pindel, varscan2
- IL4I1 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV62008895; called by muse, mutect2, varscan2
- ILK | c.172dup p.A58Gfs*11 | Frame Shift Ins (INS) | VAF 14/67 reads (21%) | catalogued as rs770182262; called by mutect2, pindel, varscan2
- IMMP2L | c.156del p.S53Afs*9 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | catalogued as rs764675061; called by mutect2, pindel, varscan2
- INTS8 | c.832T>A p.F278I | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV58249114; called by muse, mutect2, varscan2
- IPCEF1 | c.1264del p.Q422Rfs*59 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs749464600; called by mutect2, pindel, varscan2
- IPO11 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as rs778683858, COSV57572955; called by muse, mutect2, varscan2
- IPO5 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV55152601; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67330977; called by muse, mutect2, varscan2
- IRAK1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV64110135; called by muse, mutect2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs761880048; called by mutect2, varscan2
- ITGB3 | c.2071G>A p.V691I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs534325095, COSV71383530; called by muse, mutect2, varscan2
- ITGB7 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1277922719, COSV57237974; called by muse, mutect2, varscan2
- ITGB8 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.235); catalogued as rs751381514, COSV56005590, COSV56015637; called by muse, mutect2, varscan2
- ITPR3 | c.1913G>A p.C638Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770317269, COSV65406542; called by muse, mutect2, varscan2
- ITPRID2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57470070; called by muse, mutect2, varscan2
- ITPRIPL2 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as COSV67347407; called by muse, mutect2, varscan2
- KAT14 | c.1978dup p.W660Lfs*5 | Frame Shift Ins (INS) | VAF 46/242 reads (19%) | catalogued as rs1370640495; called by mutect2, varscan2
- KAT6A | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.398); catalogued as rs748715003, COSV55903706; called by muse, mutect2, varscan2
- KATNAL1 | c.1436A>C p.K479T | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66062757; called by muse, mutect2
- KBTBD13 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as rs201775551, COSV71351374; called by muse, mutect2, varscan2
- KCNH3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254762355, COSV57789867; called by muse, mutect2, varscan2
- KDM7A | c.2558T>G p.L853R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50090296; called by muse, mutect2, varscan2
- KIAA1549 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV54307481; called by muse, mutect2
- KIAA1958 | c.1690A>C p.S564R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV61722038; called by muse, mutect2, varscan2
- KIF1B | c.3446C>A p.A1149E (on ENST00000377086 / NM_001365952.1; = p.A1103E on NM_015074.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV55804559; called by muse, mutect2, varscan2
- KIF4B | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70528215; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 38/128 reads (30%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KLF6 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs758505830, COSV51493986; called by muse, mutect2, varscan2
- KLHL22 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs985869467, COSV61020029; called by muse, mutect2, varscan2
- KRT19 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs972920324, COSV54178291; called by muse, mutect2, varscan2
- KRT33B | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52440377, COSV52441682; called by muse, mutect2, varscan2
- KRT84 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs758224274, COSV57770931, COSV57771264; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDLRAD4 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs373454201, COSV63334589; called by muse, mutect2, varscan2
- LENG8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs754715683, COSV58726261, COSV58728447; called by muse, mutect2, varscan2
- LILRA2 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.401); catalogued as COSV52189088, COSV52191649; called by muse, mutect2, varscan2
- LIPH | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as rs777597150, COSV56183053; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs780042765; called by mutect2, varscan2
- LLGL1 | c.2665G>A p.V889I | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs746158258, COSV57496580; called by muse, mutect2, varscan2
- LRFN4 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV58920907; called by muse, mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 21/99 reads (21%) | catalogued as rs139915490; called by mutect2, varscan2
- LRP12 | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as rs540727474, COSV52626508; called by muse, mutect2, varscan2
- LRRC36 | c.487del p.S163Afs*7 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as COSV99338780; called by mutect2, pindel, varscan2
- LRRN3 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV57817923; called by muse, mutect2
- LRRN3 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs773718458, COSV57817929, COSV57822309; called by muse, mutect2, varscan2
- LRRTM3 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.127); catalogued as COSV63662476; called by muse, mutect2, varscan2
- LTN1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV63733161; called by muse, mutect2, varscan2
- MAGI1 | c.3830A>G p.N1277S | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs779070587, COSV58317325; called by muse, mutect2, varscan2
- MAGI1 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | catalogued as rs773082777, COSV58317334; called by muse, varscan2
- MAP3K13 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53984557, COSV53991953; called by muse, mutect2, varscan2
- MAPK4 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs373566179; called by muse, mutect2, varscan2
- MASP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775120367, COSV68896171; called by muse, mutect2, varscan2
- MAST1 | c.2743G>A p.A915T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV52242323, COSV52250749; called by muse, mutect2, varscan2
- MBD1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs376154307, COSV54007750; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 41/192 reads (21%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MCTP2 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV59141659, COSV59151071; called by muse, mutect2, varscan2
- MED13 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs771988136, COSV67262276; called by muse, mutect2, varscan2
- MED13L | c.6232G>A p.G2078S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.433); catalogued as COSV56116868; called by muse, mutect2
- MED23 | c.444T>G p.I148M | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV63430695; called by muse, mutect2, varscan2
- MELTF | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs746860496, COSV56379501; called by muse, mutect2, varscan2
- MFSD13A | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs766520687, COSV53266543; called by muse, mutect2
- MGA | c.9034C>T p.P3012S (on ENST00000219905 / NM_001164273.1; = p.P2803S on NM_001080541.2) | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54950064; called by muse, mutect2, varscan2
- MICAL2 | c.4254del p.S1420Vfs*15 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | catalogued as rs748491120; called by mutect2, pindel, varscan2
- MIEN1 | c.300A>C p.E100D | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV54064953; called by muse, mutect2, varscan2
- MKI67 | c.9233A>G p.K3078R | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as COSV64073032; called by muse, mutect2
- MKI67 | c.5942G>A p.C1981Y | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.855); catalogued as COSV64073037; called by muse, mutect2, varscan2
- MKI67 | c.2792C>T p.T931I | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV64073040; called by muse, mutect2, varscan2
- MLF1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs747924457, COSV63032861; called by muse, mutect2, varscan2
- MORC2 | c.1813-3del | Splice Region (DEL) | VAF 4/29 reads (14%) | catalogued as rs777649506, COSV53202254; called by pindel, varscan2
- MORN3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs370549242; called by muse, mutect2, varscan2
- MRC2 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100316342, COSV57637436; called by muse, mutect2, varscan2
- MRPL15 | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV52637099; called by muse, mutect2, varscan2
- MTA2 | c.2005T>A p.*669Rext*85 | Nonstop Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53469029; called by muse, mutect2
- MTDH | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1352171402, COSV60342976; called by muse, mutect2
- MTMR11 | c.1225C>T p.R409* (on ENST00000439741 / NM_001145862.2; = p.R337* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as rs782759787, COSV54964566; called by muse, mutect2
- MTTP | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55504335; called by muse, mutect2, varscan2
- MYADM | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61238767; called by muse, mutect2, varscan2
- MYCN | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747568578, COSV55257881, COSV55257901; called by muse, varscan2
- MYH9 | c.3799G>A p.V1267M | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs756528783, COSV53382874; called by muse, mutect2, varscan2
- MYLK2 | c.1697A>T p.K566M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV65658682; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NCAM2 | c.1928A>G p.K643R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.748); catalogued as COSV53060661, COSV99525608; called by muse, mutect2, varscan2
- NCAM2 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV53060673; called by muse, mutect2
- NCAPG2 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV51985292; called by muse, mutect2, varscan2
- NCF2 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV62314907; called by muse, mutect2, varscan2
- NCKAP5 | c.202del p.A68Pfs*6 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs1456601728; called by mutect2, pindel, varscan2
- NCOA2 | c.3496G>A p.A1166T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51218530; called by muse, mutect2, varscan2
- NCOR2 | c.1795del p.Q599Sfs*11 | Frame Shift Del (DEL) | VAF 34/162 reads (21%) | catalogued as COSV62295179; called by mutect2, varscan2
- NDUFAF6 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV54407481; called by muse, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 57/111 reads (51%) | catalogued as rs747914168; called by mutect2, varscan2
- NEB | c.5150G>A p.R1717H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747091795, COSV50836162; called by muse, mutect2, varscan2
- NEFM | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV55330931; called by muse, mutect2, varscan2
- NEK7 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs750418872, COSV66314317; called by muse, mutect2, varscan2
- NET1 | c.1091A>G p.Y364C (on ENST00000355029 / NM_001047160.3; = p.Y310C on NM_005863.5) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV61790951; called by muse, mutect2, varscan2
- NFXL1 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs139473913, COSV61198278; called by muse, mutect2, varscan2
- NICN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748614806, COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NIPBL | c.1439T>C p.I480T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs756257801, COSV56944643; called by muse, mutect2, varscan2
- NIPSNAP2 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV59050437; called by muse, mutect2, varscan2
- NLGN2 | c.1504del p.D502Mfs*34 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as COSV100081005, COSV100081015; called by mutect2, pindel, varscan2
- NLRP14 | c.1679T>C p.L560S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs375097983; called by muse, mutect2, varscan2
- NLRP8 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs375192759; called by muse, mutect2, varscan2
- NOL6 | c.2911C>T p.Q971* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as COSV53039696; called by muse, mutect2, varscan2
- NOL6 | c.2704C>T p.R902* | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | catalogued as rs867350221, COSV53039094; called by muse, mutect2, varscan2
- NOP56 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780014888, COSV61388668; called by muse, mutect2, varscan2
- NOS3 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs750442776, COSV52487013; called by muse, mutect2, varscan2
- NPAS1 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.88); catalogued as COSV71383884; called by muse, mutect2, varscan2
- NPAT | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1565304932, COSV53716516; called by muse, mutect2
- NPR2 | c.2370C>T p.N790= | Splice Region (SNP) | VAF 43/125 reads (34%) | catalogued as COSV61039965; called by muse, mutect2, varscan2
- NRXN1 | c.3721C>T p.R1241C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60485335; called by muse, mutect2, varscan2
- NRXN1 | c.471dup p.L158Afs*29 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | catalogued as rs774889610; called by mutect2, pindel
- NUFIP1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64790664, COSV64791723; called by muse, mutect2, varscan2
- NUP98 | c.5269G>A p.V1757M (on ENST00000359171 / NM_001365126.1; = p.V1740M on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as rs761211053, COSV51708865; called by muse, mutect2, varscan2
- NVL | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs367715317; called by muse, mutect2, varscan2
- NXF1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.1); catalogued as rs1023717509, COSV53672575; called by muse, mutect2, varscan2
- NXPE1 | c.566C>T p.A189V (on ENST00000424269; = p.A47V on NM_152315.5) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760378519, COSV52627100; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OCA2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs151118268; called by muse, mutect2, varscan2
- ODC1 | c.915C>T p.D305= | Splice Region (SNP) | VAF 41/134 reads (31%) | catalogued as rs1470452817, COSV52171722; called by muse, mutect2, varscan2
- OGDH | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56046380; called by muse, mutect2
- OGFRL1 | c.546+2T>C p.X182_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV64971723; called by muse, mutect2, varscan2
- OR10P1 | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs774620519, COSV59006810; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2G6 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV58573872, COSV99080278; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 79/412 reads (19%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR51F2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV59063949, COSV59064687; called by muse, mutect2, varscan2
- OR6Y1 | c.399T>A p.N133K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV56928476; called by muse, mutect2, varscan2
- OR8J3 | c.383A>T p.N128I | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV56879670; called by muse, mutect2, varscan2
- OSBPL5 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs370324105, COSV55139930; called by muse, mutect2, varscan2
- OXA1L | c.368G>T p.S123I (on ENST00000285848; = p.S63I on NM_005015.5) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.189); catalogued as rs561401014, COSV53536516; called by muse, mutect2, varscan2
- OXER1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs777119606, COSV54309986; called by muse, mutect2, varscan2
- P3H1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs750685729, COSV52532016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALD1 | c.1900dup p.R634Pfs*6 | Frame Shift Ins (INS) | VAF 15/62 reads (24%) | catalogued as rs745381684; called by mutect2, pindel, varscan2
- PAN2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV57752982; called by muse, mutect2, varscan2
- PARP6 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.897); catalogued as rs894536131, COSV53002274; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 23/82 reads (28%) | catalogued as rs756801119; called by mutect2, varscan2
- PCDH1 | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs767284701, COSV54611745, COSV54617061; called by muse, mutect2, varscan2
- PCDH10 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52088912; called by muse, mutect2, varscan2
- PCDH15 | c.4988del p.N1663Tfs*157 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as COSV64672255; called by mutect2, pindel, varscan2
- PCDH15 | c.4315C>T p.P1439S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.437); catalogued as COSV57270808; called by muse, mutect2, varscan2
- PCDH18 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV61266800; called by muse, mutect2, varscan2
- PCDH19 | c.2476C>T p.R826C (on ENST00000373034 / NM_001184880.2; = p.R779C on NM_020766.3) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs914370738, COSV55257430, COSV55258717; called by muse, mutect2, varscan2
- PCDH8 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs548787593, COSV58811168; called by muse, mutect2, varscan2
- PCDHA3 | c.2228G>A p.S743N | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV63539472; called by muse, mutect2, varscan2
- PCDHB2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs782442205; called by muse, mutect2, varscan2
- PCDHGA12 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.586); catalogued as COSV52745012; called by muse, mutect2, varscan2
- PCED1B | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV71394953; called by muse, mutect2, varscan2
- PCNX1 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV99454342; called by muse, mutect2, varscan2
- PDZD2 | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs371935614; called by muse, mutect2, varscan2
- PDZD7 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs768381051, COSV64645534; called by muse, mutect2, varscan2
- PEX6 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754790139, COSV55102055; called by muse, mutect2, varscan2
- PFKFB2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | PolyPhen benign (0.147); catalogued as COSV65547356; called by muse, mutect2, varscan2
- PGA5 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.053); catalogued as COSV56714971; called by muse, mutect2, varscan2
- PGAM2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as rs1224215042, COSV51977299; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs769717544; called by mutect2, varscan2
- PHIP | c.2101A>T p.M701L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV51502036; called by muse, mutect2, varscan2
- PHKG2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60311159; called by muse, mutect2, varscan2
- PKMYT1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1346776313, COSV51890992, COSV99234151; called by muse, mutect2, varscan2
- PLA2R1 | c.2988del p.T997Pfs*16 | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | catalogued as rs755922927; called by mutect2, pindel, varscan2
- PLCB4 | c.3307C>T p.R1103W | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771325329, COSV53795342; called by muse, mutect2, varscan2
- PLCG1 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs1190320310, COSV54815245; called by muse, mutect2, varscan2
- PLEKHA5 | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs774894158, COSV54695622; called by muse, mutect2, varscan2
- PLEKHH2 | c.2768T>C p.V923A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56750518; called by muse, mutect2, varscan2
- PLOD1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs141809154; called by muse, mutect2, varscan2
- PLXDC1 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs964061231, COSV59549826; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 30/62 reads (48%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNA4 | c.2873A>T p.D958V | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV58109670; called by muse, mutect2, varscan2
- PLXND1 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs773387450, COSV60710098; called by muse, mutect2, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | catalogued as COSV64722654; called by mutect2, pindel, varscan2
- POGZ | c.3274A>G p.T1092A | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV51850624; called by muse, mutect2, varscan2
- POLA2 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV55481205; called by muse, mutect2, varscan2
- POLG | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV51520100; called by muse, mutect2, varscan2
- POLQ | c.4228C>A p.L1410M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV51747354; called by muse, mutect2, varscan2
- POLR1C | c.768C>A p.C256* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV54827955; called by muse, mutect2, varscan2
- POU4F3 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV57942669; called by muse, mutect2, varscan2
- PPARGC1A | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as rs765713824, COSV53525177; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | catalogued as rs775130624; called by mutect2, pindel, varscan2
- PPM1F | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs549205418, COSV54283229; called by muse, mutect2, varscan2
- PPP1R13L | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62908047; called by muse, mutect2, varscan2
- PPP1R3D | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62563984; called by muse, mutect2, varscan2
- PPP1R9A | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56883995; called by muse, mutect2, varscan2
- PPP2R2B | c.1281A>G p.I427M (on ENST00000394409; = p.I493M on NM_181674.2) | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV60756097; called by muse, varscan2
- PRAG1 | c.3746A>G p.Y1249C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100422766, COSV58157404; called by muse, mutect2
- PRAMEF14 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs752175196, COSV100577268; called by muse, mutect2
- PRC1 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as rs777202528, COSV62694375; called by muse, mutect2, varscan2
- PRDM10 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1460373716, COSV58799742; called by muse, mutect2, varscan2
- PRKDC | c.6791A>T p.D2264V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV58045900; called by muse, mutect2, varscan2
- PRKDC | c.4165G>A p.V1389I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1445022618, COSV58045913; called by muse, mutect2, varscan2
- PRKDC | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.295); catalogued as rs903157181, COSV58045928; called by muse, mutect2, varscan2
- PRPF39 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.101); catalogued as COSV63276570; called by muse, mutect2, varscan2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 39/171 reads (23%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PRR19 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV100004015, COSV56624041, COSV56625287; called by muse, mutect2, varscan2
- PRRX1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1485111813, COSV53411616, COSV53419369; called by muse, mutect2, varscan2
- PSG7 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 22/531 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV68444449; called by muse, mutect2
- PTPRD | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758558790, COSV61931118, COSV61932074; called by muse, mutect2, varscan2
- PTPRM | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59847291; called by muse, mutect2, varscan2
- PTPRS | c.2021T>C p.I674T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV53612294; called by muse, mutect2, varscan2
- QSER1 | c.2309T>C p.M770T (on ENST00000399302; = p.M899T on NM_001076786.3) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV67899747; called by muse, mutect2, varscan2
- QTRT2 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55559055; called by muse, mutect2, varscan2
- RAB26 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV52954143; called by muse, mutect2, varscan2
- RABEPK | c.841A>G p.T281A | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV52334270; called by muse, mutect2, varscan2
- RABGGTB | c.830del p.G277Dfs*47 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | catalogued as rs757854818; called by mutect2, pindel, varscan2
- RABL6 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173411995, COSV100273425, COSV61033778; called by muse, mutect2, varscan2
- RALGAPA1 | c.5412C>T p.C1804= | Splice Region (SNP) | VAF 22/83 reads (27%) | catalogued as COSV51878087; called by muse, mutect2, varscan2
- RALGAPA2 | c.5379del p.F1793Lfs*9 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs1266187100, COSV104390311; called by mutect2, pindel, varscan2
- RALY | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55780116; called by muse, mutect2, varscan2
- RASL10B | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1555596992; called by muse, mutect2, varscan2
- RBM15B | c.1781G>T p.R594L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60041154; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs762006287; called by mutect2, varscan2
- REC8 | c.827dup p.E277Gfs*85 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | catalogued as rs766853930; called by mutect2, varscan2
- RECQL4 | c.3065G>A p.R1022H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs560476442, COSV56739554; called by muse, mutect2, varscan2
- RECQL5 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765614838, COSV53126975; called by muse, mutect2
- REP15 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV57288576; called by muse, mutect2, varscan2
- RFPL4B | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs369372940; called by muse, mutect2, varscan2
- RFX1 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs750251703, COSV54328240; called by muse, mutect2, varscan2
- RGMA | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs1335782562, COSV61233281; called by muse, mutect2, varscan2
- RIC3 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58300746; called by muse, mutect2, varscan2
- RIMBP2 | c.3116G>A p.R1039H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs763559163, COSV55466753; called by muse, mutect2, varscan2
- RIMS2 | c.4396A>C p.K1466Q (on ENST00000666250 / NM_001348490.2; = p.K1037Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51659272; called by muse, mutect2
- RNF213 | c.2427+2T>G p.X809_splice | Splice Site (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100173141; called by muse, mutect2, varscan2
- RNF220 | c.1687A>G p.R563G | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59189974; called by muse, mutect2, varscan2
- RNF25 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV55306335; called by muse, mutect2
- ROGDI | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59020877; called by muse, mutect2, varscan2
- RPL7A | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.262); catalogued as rs587630123, COSV59297375; called by muse, mutect2, varscan2
- RUNX1 | c.956G>A p.R319H (on ENST00000344691 / NM_001001890.3; = p.R346H on NM_001754.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1282562937, COSV55869219; ClinVar: uncertain significance; called by muse, mutect2
- RUSC1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52738458; called by muse, mutect2, varscan2
- RXFP3 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs757464013, COSV57504385; called by muse, mutect2, varscan2
- RXFP4 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs754256552, COSV58142039; called by muse, mutect2, varscan2
- RYR1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922761, CM064215, COSV62091320; called by muse, mutect2, varscan2
- SAMD3 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV60774417; called by muse, mutect2, varscan2
- SDK1 | c.2098A>G p.I700V | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1220389635, COSV67359174; called by muse, mutect2, varscan2
- SDK2 | c.2513A>T p.E838V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV66182427; called by muse, mutect2, varscan2
- SEMA6A | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 101/359 reads (28%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.999); catalogued as COSV56709658; called by muse, mutect2, varscan2
- SETD1A | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52685583; called by muse, mutect2, varscan2
- SF1 | c.1547G>A p.S516N | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.483); catalogued as rs1472496223, COSV57111985; called by muse, mutect2, varscan2
- SFRP2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs533800119, COSV56836961; called by muse, mutect2, varscan2
- SGCA | c.1015G>T p.G339W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56248636; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs747473028; called by mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 39/179 reads (22%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH3BP4 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV60642688, COSV60646872; called by muse, mutect2, varscan2
- SH3BP5L | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs994887846, COSV100821992, COSV63538839; called by muse, mutect2, varscan2
- SHANK2 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV53588565; called by muse, mutect2, varscan2
- SIPA1L2 | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV53384819; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 58/174 reads (33%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A1 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57708518; called by muse, mutect2
- SLC12A6 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV62542769; called by muse, mutect2, varscan2
- SLC13A2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.19); catalogued as rs11568463, CM109403; called by muse, mutect2, varscan2
- SLC20A2 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60602177; called by muse, mutect2, varscan2
- SLC22A16 | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57927947; called by muse, mutect2, varscan2
- SLC25A12 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs138477378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A27 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV51493942; called by muse, mutect2, varscan2
- SLC30A6 | c.617T>A p.L206H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1470068955, COSV50872007; called by muse, mutect2, varscan2
- SLC35F3 | c.170C>T p.T57M (on ENST00000366617 / NM_001300845.1; = p.T126M on NM_173508.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV64018579, COSV64019382; called by muse, mutect2, varscan2
- SLC5A6 | c.1424T>C p.I475T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV60158616; called by muse, mutect2, varscan2
- SLC6A17 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991663; called by muse, mutect2, varscan2
- SLCO5A1 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs548263300, COSV52655083; called by muse, mutect2, varscan2
- SMARCA4 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs755455174, COSV60788764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCD2 | c.892T>C p.C298R | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV56738130; called by muse, mutect2, varscan2
- SMARCD2 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.986); catalogued as rs1214587983, COSV56738144; called by muse, mutect2, varscan2
- SMYD4 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV59710804; called by muse, mutect2, varscan2
- SORBS2 | c.143C>G p.T48S (on ENST00000284776 / NM_021069.5; = p.T94S on NM_003603.6) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52993328; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOS2 | c.3489G>T p.K1163N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV53564523; called by muse, mutect2, varscan2
- SOX7 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs370342985; called by muse, mutect2, varscan2
- SPATA18 | c.1111T>G p.F371V | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV54642282; called by muse, mutect2, varscan2
- SPICE1 | c.1892C>A p.S631Y | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.509); catalogued as rs1559957388, COSV55618750; called by muse, mutect2, varscan2
- SPINK5 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.803); catalogued as CM025502, COSV56249937; called by muse, mutect2, varscan2
- SPPL2B | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.748); catalogued as rs1323266673, COSV66316815; called by muse, mutect2, varscan2
- SPRY4 | c.727G>A p.V243M (on ENST00000434127 / NM_001127496.3; = p.V266M on NM_030964.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs201009569; called by muse, mutect2, varscan2
- SPTBN1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61686244; called by muse, mutect2
- SRCAP | c.7091C>T p.P2364L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs1189389984, COSV52668608, COSV99350162; called by muse, mutect2, varscan2
- SRGAP2 | c.2504A>G p.K835R (on ENST00000624873 / NM_001170637.4; = p.K836R on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55334127; called by muse, mutect2, varscan2
- SRGAP3 | c.2548dup p.V850Gfs*10 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | catalogued as rs759698239; called by mutect2, varscan2
- SRPRB | c.411-1G>T p.X137_splice | Splice Site (SNP) | VAF 106/445 reads (24%) | catalogued as COSV71749026; called by muse, mutect2, varscan2
- SRRM4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as rs775854693, COSV57410316; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 35/100 reads (35%) | catalogued as rs753297385; called by mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs752994755; called by mutect2, varscan2
- STEAP2 | c.680del p.F227Sfs*9 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as rs754344704; called by mutect2, varscan2
- STIL | c.3392G>A p.S1131N | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); catalogued as COSV54548532; called by muse, mutect2, varscan2
- STK11IP | c.2785del p.Q929Sfs*39 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as rs1559188516; called by mutect2, pindel, varscan2
- STRADA | c.944C>T p.S315L (on ENST00000336174 / NM_001363786.1; = p.S278L on NM_153335.6) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs375825074; called by muse, varscan2
- STXBP5 | c.2602G>T p.G868C (on ENST00000321680 / NM_001127715.2; = p.G832C on NM_139244.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV51648781; called by muse, mutect2, varscan2
- SUCO | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV55262843; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SUPT16H | c.2302-1G>T p.X768_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV53522753; called by muse, mutect2
- SUPT16H | c.2285A>G p.D762G | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53522763; called by muse, mutect2, varscan2
- SYBU | c.737G>A p.R246H (on ENST00000276646 / NM_001099754.2; = p.R245H on NM_017786.6) | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575944059, COSV52615037, COSV52621483; called by muse, mutect2, varscan2
- SYNPO | c.1486A>C p.S496R (on ENST00000394243 / NM_001166208.2; = p.S252R on NM_007286.6) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV56938884; called by muse, mutect2, varscan2
- SYTL5 | c.1987T>C p.W663R | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52899003; called by muse, mutect2, varscan2
- TADA2B | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53826835; called by muse, mutect2, varscan2
- TAF4 | c.3136A>C p.T1046P | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.522); catalogued as COSV53335199; called by muse, mutect2, varscan2
- TAP1 | c.2083+1G>A p.X695_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV62753947, COSV62755086; called by muse, mutect2, varscan2
- TBC1D13 | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1448842071, COSV56353606; called by muse, mutect2, varscan2
- TBC1D8 | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65210373; called by muse, mutect2, varscan2
- TBX1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1383559813, COSV60352877; called by muse, mutect2, varscan2
- TBX10 | c.291dup p.F98Lfs*72 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs748952707; called by mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TDP2 | c.24G>T p.E8D | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV57763803; called by muse, mutect2, varscan2
- TECTA | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV50691083; called by muse, mutect2, varscan2
- TEX14 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746748706, COSV53612924; called by muse, varscan2
- TEX15 | c.8227C>T p.R2743W (on ENST00000256246; = p.R3126W on NM_001350162.2) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs750126653, COSV56341284; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs746975641; called by mutect2, varscan2
- THRA | c.222+1G>A p.X74_splice | Splice Site (SNP) | VAF 17/143 reads (12%) | catalogued as COSV52841147; called by muse, mutect2, varscan2
- THRAP3 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 142/379 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1042061001, COSV63566888, COSV63569175, COSV63569952; called by muse, mutect2, varscan2
- TICRR | c.3156C>G p.D1052E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV51538734; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TLL1 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV50263933; called by muse, mutect2, varscan2
- TLN2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV60886592; called by muse, mutect2, varscan2
- TM9SF4 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54105044; called by muse, mutect2
- TMC7 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV58581927, COSV58582815; called by muse, mutect2, varscan2
- TMEM17 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV59022463; called by muse, mutect2, varscan2
- TMEM178A | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV56141172; called by muse, mutect2, varscan2
- TMEM198 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.146); catalogued as COSV54714164; called by muse, mutect2, varscan2
- TMEM202 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58982005; called by muse, mutect2, varscan2
- TMEM51 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs766562634, COSV65690415; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs781830688; called by mutect2, varscan2
- TMPO | c.295dup p.T99Nfs*2 | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | catalogued as rs770800449; called by mutect2, varscan2
- TMPRSS11E | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100542246; called by muse, mutect2, varscan2
- TNPO2 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV63507733; called by muse, mutect2, varscan2
- TNRC6A | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs753463751, COSV59361986, COSV59362271; called by muse, mutect2, varscan2
- TNS4 | c.83_89del p.L28Qfs*24 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as rs1382921921; called by mutect2, pindel, varscan2
- TRA2A | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51715993, COSV99767776; called by muse, mutect2, varscan2
- TRIM45 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56712716; called by muse, mutect2, varscan2
- TRIOBP | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.003); catalogued as rs551767434, COSV60374727; called by muse, mutect2, varscan2
- TROAP | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV57743327; called by muse, mutect2, varscan2
- TRUB1 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53928521; called by muse, mutect2, varscan2
- TTK | c.2490+4_2490+7del p.X830_splice | Splice Site (DEL) | VAF 20/86 reads (23%) | catalogued as rs758164066; called by pindel, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL9 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60590156; called by muse, mutect2, varscan2
- TTN | c.100563G>T p.W33521C (on ENST00000591111; = p.W26097C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/344 reads (10%) | PolyPhen probably damaging (0.998); catalogued as COSV59920090; called by muse, mutect2
- TTN | c.61515G>T p.K20505N (on ENST00000591111; = p.K13081N on NM_003319.4) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | PolyPhen benign (0.028); catalogued as COSV59896251, COSV59920126; called by muse, mutect2, varscan2
- TTN | c.15836A>G p.E5279G (on ENST00000591111; = p.E4352G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/274 reads (34%) | PolyPhen benign (0); catalogued as COSV59893538, COSV59920215; called by muse, mutect2, varscan2
- TULP4 | c.1632-1G>T p.X544_splice | Splice Site (SNP) | VAF 32/111 reads (29%) | catalogued as COSV65572968; called by muse, mutect2, varscan2
- TULP4 | c.2998C>T p.Q1000* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV65572978; called by muse, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs760251146; called by mutect2, varscan2
- UBE4A | c.2197G>C p.G733R (on ENST00000252108 / NM_001204077.2; = p.G740R on NM_004788.4) | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52802955, COSV99348452; called by muse, mutect2, varscan2
- UBE4B | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs772803836, COSV53528269; called by muse, mutect2
- UBN1 | c.2923G>A p.G975R | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs766000805, COSV52166308; called by muse, mutect2, varscan2
- UBR4 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs369976219; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 44/126 reads (35%) | catalogued as rs763652408; called by mutect2, varscan2
- UGGT1 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1380378647, COSV52133042; called by muse, mutect2
- UMODL1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs370301179; called by muse, mutect2, varscan2
- UNC13C | c.6128T>C p.V2043A | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV52849186; called by muse, mutect2, varscan2
- UNC13D | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs866295247, COSV52883294; called by muse, mutect2, varscan2
- UPF1 | c.1145C>T p.A382V (on ENST00000599848 / NM_001297549.2; = p.A371V on NM_002911.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as COSV53194317; called by muse, mutect2, varscan2
- VAX2 | c.719del p.P240Hfs*36 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs782186760; called by mutect2, pindel, varscan2
- VCAM1 | c.2195T>C p.V732A | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54118107; called by muse, mutect2, varscan2
- VGF | c.1329C>G p.D443E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV50800850; called by muse, mutect2, varscan2
- VPS13A | c.3109A>G p.K1037E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as CM022628, COSV62426126; called by muse, mutect2
- VPS39 | c.2075G>A p.R692Q (on ENST00000348544 / NM_001301138.2; = p.R681Q on NM_015289.5) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs541840149, COSV58788229; called by muse, mutect2, varscan2
- VSIG10 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs751715997, COSV63652353; called by muse, mutect2, varscan2
- VSTM4 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100251345; called by muse, mutect2, varscan2
- VWA3A | c.3486G>A p.W1162* | Nonsense Mutation (SNP) | VAF 44/160 reads (28%) | catalogued as rs753557515, COSV55388595; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs756173793; called by mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | catalogued as rs1158703313; called by mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR86 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57838545; called by muse, mutect2
- WDTC1 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60087422; called by muse, mutect2, varscan2
- WNT9A | c.500del p.G167Afs*38 | Frame Shift Del (DEL) | VAF 29/194 reads (15%) | catalogued as rs779992922; called by mutect2, pindel, varscan2
- WWC3 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs138880852, COSV66501460; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | catalogued as rs745648385; called by mutect2, pindel
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs762052135; called by mutect2, varscan2
- YME1L1 | c.2111G>A p.S704N (on ENST00000326799 / NM_139312.3; = p.S647N on NM_014263.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV58758303; called by muse, mutect2, varscan2
- YY1AP1 | c.375G>T p.K125N (on ENST00000295566 / NM_139118.2; = p.K48N on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV55119493, COSV55119671; called by muse, mutect2, varscan2
- YY2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.369); catalogued as COSV63410907; called by muse, mutect2, varscan2
- ZBED1 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58131109; called by muse, mutect2
- ZBTB46 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55507427; called by muse, mutect2, varscan2
- ZC3H4 | c.3827C>T p.P1276L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1037009516, COSV53410805; called by muse, mutect2, varscan2
- ZDBF2 | c.1827A>C p.Q609H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV65622754; called by muse, mutect2, varscan2
- ZFAND4 | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60857980; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs563751025; called by mutect2, varscan2
- ZFP57 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV65305772; called by muse, mutect2, varscan2
- ZFYVE28 | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs199856439, COSV99342507; called by muse, mutect2, varscan2
- ZNF208 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68101788; called by muse, mutect2, varscan2
- ZNF234 | c.631A>T p.K211* | Nonsense Mutation (SNP) | VAF 22/201 reads (11%) | catalogued as COSV70602936; called by muse, mutect2, varscan2
- ZNF333 | c.309del p.X103_splice | Splice Site (DEL) | VAF 13/59 reads (22%) | catalogued as COSV52886851; called by mutect2, pindel, varscan2
- ZNF408 | c.939T>A p.S313R | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV61237720; called by muse, mutect2, varscan2
- ZNF420 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.626); catalogued as rs764679377, COSV58492958; called by muse, mutect2, varscan2
- ZNF460 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs775245618, COSV64415375; called by muse, mutect2
- ZNF483 | c.761G>T p.R254M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58514703; called by muse, mutect2, varscan2
- ZNF536 | c.3322C>A p.P1108T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62819950; called by muse, mutect2, varscan2
- ZNF556 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs746710684, COSV56910873; called by muse, mutect2, varscan2
- ZNF598 | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1017869343, COSV70910034; called by muse, mutect2, varscan2
- ZNF618 | c.2119C>T p.R707C (on ENST00000374126 / NM_001318042.2; = p.R614C on NM_133374.2) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs368835232; called by muse, mutect2
- ZNF667 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV52631847, COSV99410787; called by muse, mutect2, varscan2
- ZNF708 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV63607009; called by muse, mutect2, varscan2
- ZNF780A | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61814705; called by muse, mutect2, varscan2
- ZNF787 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV54419471; called by muse, mutect2, varscan2
- ZNF862 | c.1527del p.P510Lfs*7 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | catalogued as COSV56223579; called by mutect2, pindel, varscan2
- ZNF875 | c.1812del p.K605Sfs*91 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs775240804; called by mutect2, pindel, varscan2
- ACACA | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- ACTR6 | c.942del p.F314Lfs*6 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- ADA2 | c.1202del p.K401Rfs*5 (on ENST00000262607; = p.K160Rfs*5 on NM_177405.3) | Frame Shift Del (DEL) | VAF 45/172 reads (26%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.16395del p.F5465Lfs*13 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- AMBRA1 | c.1310del p.P437Rfs*9 (on ENST00000458649 / NM_001367468.1; = p.P347Rfs*9 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- AMER3 | c.1669del p.A557Rfs*127 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- AMOTL1 | c.879del p.S295Pfs*26 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | called by mutect2, pindel, varscan2
- ANGPT1 | c.572del p.N191Tfs*4 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- AOC1 | c.1476del p.E493Rfs*13 | Frame Shift Del (DEL) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.1068dup p.L357Tfs*18 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.533_534del p.T178Sfs*15 | Frame Shift Del (DEL) | VAF 32/129 reads (25%) | called by pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 41/174 reads (24%) | called by mutect2, pindel, varscan2
- ASB11 | c.68del p.F23Sfs*5 | Frame Shift Del (DEL) | VAF 44/79 reads (56%) | called by mutect2, varscan2
- B3GAT1 | c.333del p.H111Qfs*19 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- BACH2 | c.257dup p.F87Lfs*28 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- BAZ1B | c.2978dup p.L993Ffs*3 | Frame Shift Ins (INS) | VAF 38/190 reads (20%) | called by pindel, varscan2
- BCR | c.673del p.D225Mfs*27 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- BMPR2 | c.393del p.P132Hfs*20 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- BTBD3 | c.176dup p.K60Efs*6 | Frame Shift Ins (INS) | VAF 63/332 reads (19%) | called by mutect2, pindel, varscan2
- BTBD7 | c.501dup p.K168* | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- C1orf54 | c.123del p.S42Vfs*22 | Frame Shift Del (DEL) | VAF 27/176 reads (15%) | called by mutect2, pindel, varscan2
- C5 | c.2940del p.G981Dfs*4 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- CABLES2 | c.1060del p.H354Mfs*4 | Frame Shift Del (DEL) | VAF 51/277 reads (18%) | called by mutect2, pindel, varscan2
- CACNA1S | c.3835_3837del p.F1279del | In Frame Del (DEL) | VAF 30/104 reads (29%) | called by pindel, varscan2
- CCDC88A | c.1845del p.E616Nfs*33 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- CDH9 | c.1293del p.F431Lfs*13 | Frame Shift Del (DEL) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- CEP290 | c.634_635del p.N212Lfs*2 | Frame Shift Del (DEL) | VAF 55/247 reads (22%) | called by mutect2, pindel, varscan2
- CEP63 | c.436del p.I146* | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- CEP83 | c.1706dup p.R570Efs*6 | Frame Shift Ins (INS) | VAF 66/232 reads (28%) | called by mutect2, pindel, varscan2
- CIAO3 | c.436del p.I146* | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | called by mutect2, pindel, varscan2
- CMYA5 | c.498del p.G167Afs*4 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- COPA | c.2454del p.F818Lfs*65 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- COQ2 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- CTIF | c.790del p.E264Rfs*12 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- CYP26C1 | c.1531del p.L511Sfs*18 | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- DHX29 | c.2421del p.K807Nfs*16 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by pindel, varscan2
- DMXL2 | c.5763dup p.D1922Rfs*4 | Frame Shift Ins (INS) | VAF 44/210 reads (21%) | called by mutect2, varscan2
- EGFR | c.797del p.P266Hfs*14 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | called by mutect2, pindel, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by mutect2, varscan2
- EIF5B | c.1159del p.R387Efs*15 | Frame Shift Del (DEL) | VAF 37/140 reads (26%) | called by mutect2, pindel, varscan2
- ENPEP | c.843dup p.M282Hfs*14 | Frame Shift Ins (INS) | VAF 42/162 reads (26%) | called by mutect2, pindel, varscan2
- ENTPD7 | c.388del p.I130Sfs*23 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- ERG | c.1359dup p.A454Cfs*19 (on ENST00000398919 / NM_001243428.1; = p.A430Cfs*19 on NM_004449.4) | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | called by mutect2, varscan2
- ETV7 | c.797dup p.N267Kfs*22 | Frame Shift Ins (INS) | VAF 42/229 reads (18%) | called by mutect2, pindel, varscan2
- FBXO38 | c.2090del p.N697Tfs*32 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, varscan2
- FHDC1 | c.304del p.W102Gfs*55 | Frame Shift Del (DEL) | VAF 84/301 reads (28%) | called by mutect2, pindel, varscan2
- FOXJ1 | c.327del p.D110Tfs*11 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- FRG2C | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
- GPS1 | c.1081dup p.H361Pfs*28 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by pindel, varscan2
- GPX2 | c.278del p.G93Vfs*? | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- HAPLN1 | c.310del p.T104Pfs*11 | Frame Shift Del (DEL) | VAF 49/177 reads (28%) | called by mutect2, pindel, varscan2
- HDAC4 | c.1941del p.T648Pfs*14 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- HLA-A | c.393dup p.R132Afs*45 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- HMCN1 | c.3447_3448del p.V1151Cfs*27 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- HORMAD1 | c.229_230del p.Q77Vfs*10 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by pindel, varscan2
- HPS5 | c.2042dup p.I683Nfs*4 (on ENST00000349215 / NM_181507.2; = p.I569Nfs*4 on NM_007216.4) | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- HTT | c.7816dup p.E2606Gfs*62 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- IL31RA | c.427_428del p.M143Dfs*12 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by pindel, varscan2
- INO80 | c.2614_2615del p.I872Pfs*11 | Frame Shift Del (DEL) | VAF 45/180 reads (25%) | called by pindel, varscan2
- IPPK | c.205dup p.E69Gfs*27 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | called by mutect2, pindel, varscan2
- ITIH5 | c.1476del p.S493Afs*49 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- ITPR2 | c.7250dup p.L2417Ffs*4 | Frame Shift Ins (INS) | VAF 40/111 reads (36%) | called by mutect2, varscan2
- JARID2 | c.416del p.P139Lfs*168 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- JSRP1 | c.574dup p.R192Pfs*66 | Frame Shift Ins (INS) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- LCA5L | c.1172del p.K391Rfs*15 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- LGR5 | c.2133_2134del p.C712Pfs*87 | Frame Shift Del (DEL) | VAF 57/271 reads (21%) | called by pindel, varscan2
- LILRA6 | c.937dup p.L313Pfs*11 | Frame Shift Ins (INS) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- LPCAT3 | c.252dup p.N85* | Frame Shift Ins (INS) | VAF 78/284 reads (27%) | called by mutect2, pindel, varscan2
- MAL2 | c.326dup p.F110Ifs*19 | Frame Shift Ins (INS) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- MAP1B | c.3814dup p.L1272Pfs*3 | Frame Shift Ins (INS) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- MAP2 | c.4420del p.T1474Qfs*14 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- MARK2 | c.1888del p.A630Pfs*27 (on ENST00000402010 / NM_001039469.2; = p.A575Pfs*18 on NM_004954.5) | Frame Shift Del (DEL) | VAF 37/190 reads (19%) | called by mutect2, pindel, varscan2
- MDC1 | c.2917del p.A973Rfs*25 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- MED13 | c.5497del p.S1833Vfs*16 | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- MED13 | c.2139del p.D714Ifs*15 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | called by mutect2, pindel, varscan2
- MLH1 | c.463_482del p.L155Efs*10 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | called by mutect2, varscan2
- MMP9 | c.1290del p.L431Cfs*6 | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | called by mutect2, pindel, varscan2
- MPHOSPH10 | c.711dup p.E238* | Frame Shift Ins (INS) | VAF 25/96 reads (26%) | called by mutect2, varscan2
- MSL3 | c.1319dup p.G441Rfs*2 (on ENST00000312196 / NM_078629.4; = p.G275Rfs*2 on NM_006800.4) | Frame Shift Ins (INS) | VAF 73/145 reads (50%) | called by mutect2, pindel, varscan2
- MTG1 | c.320del p.N107Mfs*8 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- MYCN | c.1005del p.S336Lfs*15 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel, varscan2
- MYOCD | c.374del p.N125Tfs*9 | Frame Shift Del (DEL) | VAF 91/212 reads (43%) | called by mutect2, pindel, varscan2
- NCOA6 | c.1331del p.P444Qfs*48 | Frame Shift Del (DEL) | VAF 30/205 reads (15%) | called by mutect2, pindel, varscan2
- NEDD4L | c.467del p.N156Mfs*51 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
320 further variants in this file (59 protein-altering or splice-affecting, 233 silent, 28 other) are not listed here.
